Somatic mutation profile of tumor specimen TCGA-56-7580-01A (aliquot TCGA-56-7580-01A-11D-2042-08) from TCGA case TCGA-56-7580, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 84.2 years (30,740 days).
Specimen TCGA-56-7580-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1445371f-e3bb-456e-aa16-799d4b70ee29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-7580-10A (Blood Derived Normal), aliquot TCGA-56-7580-10A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc2c8d0d-b27e-499e-86c9-f399fdbc9267

The open-access MAF lists 143 somatic variants for this specimen: 109 protein-altering or splice-affecting, 31 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 31, Nonsense Mutation 7, Frame Shift Del 4, Splice Site 3, Intron 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXP1 | c.1147-2A>G p.X383_splice | Splice Site (SNP) | VAF 17/48 reads (35%) | catalogued as rs1559621862, COSV100561469; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 64/216 reads (30%) | catalogued as rs1567556752, CM120852, COSV52811974, COSV52991347; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.1847G>C p.G616A | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as CM066525, COSV101036834; called by muse, mutect2, varscan2
- ABCC1 | c.2332C>G p.L778V | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as COSV100579311; called by muse, mutect2, varscan2
- ACE | c.3388G>A p.V1130I | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as rs575830312, COSV99326886; called by muse, mutect2, varscan2
- ACTN2 | c.2461G>T p.E821* | Nonsense Mutation (SNP) | VAF 32/96 reads (33%) | catalogued as COSV100856744; called by muse, varscan2
- AGXT2 | c.312C>G p.Y104* | Nonsense Mutation (SNP) | VAF 24/172 reads (14%) | catalogued as COSV99183737; called by muse, mutect2
- AKAP9 | c.8855G>A p.R2952Q (on ENST00000359028; = p.R2928Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs141103974; called by muse, mutect2, varscan2
- ANO5 | c.1024T>G p.C342G | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100201750; called by mutect2, varscan2
- ARID1A | c.5935A>T p.K1979* | Nonsense Mutation (SNP) | VAF 44/85 reads (52%) | catalogued as COSV100251324; called by muse, mutect2, varscan2
- ARMC8 | c.785A>G p.Y262C (on ENST00000469044 / NM_001363941.2; = p.Y248C on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as COSV100627605; called by muse, mutect2, varscan2
- ATL2 | c.635A>G p.D212G | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100184561; called by muse, mutect2, varscan2
- ATP8A1 | c.743A>T p.D248V | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV100045796; called by muse, mutect2, varscan2
- C11orf80 | c.941A>C p.E314A | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV100690857; called by muse, mutect2, varscan2
- C19orf57 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.259); catalogued as rs1165333534, COSV100694685; called by muse, mutect2, varscan2
- C6orf58 | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV100314849; called by muse, mutect2, varscan2
- C6orf58 | c.388+1G>T p.X130_splice | Splice Site (SNP) | VAF 31/142 reads (22%) | catalogued as rs373910619; called by muse, mutect2, varscan2
- CBLC | c.480G>T p.W160C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99541991; called by muse, mutect2, varscan2
- CCDC85A | c.892C>A p.P298T | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV101339455, COSV68153377; called by muse, mutect2, varscan2
- CDH9 | c.1000-1G>C p.X334_splice | Splice Site (SNP) | VAF 7/26 reads (27%) | catalogued as COSV50276196, COSV50541880, COSV99143658; called by muse, mutect2, varscan2
- CEP170B | c.1919T>G p.L640R (on ENST00000453495; = p.L569R on NM_015005.3) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.246); catalogued as COSV101371482; called by muse, mutect2
- CFAP91 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as COSV99847046; called by muse, mutect2, varscan2
- CFAP91 | c.815A>T p.E272V | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV99847048; called by muse, mutect2, varscan2
- CGNL1 | c.3060G>C p.E1020D | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.047); catalogued as COSV99848072; called by muse, mutect2, varscan2
- COL6A3 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); catalogued as rs189356869, COSV55086821; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CWF19L2 | c.2432G>T p.R811I | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99978853; called by muse, mutect2, varscan2
- DEPDC5 | c.3634C>G p.L1212V (on ENST00000400246; = p.L1281V on NM_014662.5) | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.658); catalogued as COSV99835109; called by muse, mutect2, varscan2
- DNAH8 | c.1901G>T p.S634I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.435); catalogued as COSV100544582; called by muse, mutect2, varscan2
- DOCK2 | c.3411C>A p.D1137E | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99911700; called by muse, mutect2, varscan2
- DOCK2 | c.3412C>A p.H1138N | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.274); catalogued as COSV99911701; called by muse, mutect2, varscan2
- ERBB4 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.99); PolyPhen probably damaging (1); catalogued as rs867148133, COSV53566690, COSV53591179; called by muse, mutect2, varscan2
- FBXO21 | c.1483G>A p.D495N (on ENST00000330622 / NM_033624.3; = p.D488N on NM_015002.3) | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs766185486, COSV100401698; called by muse, mutect2, varscan2
- FOXD4 | c.915G>T p.R305S | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as COSV100070811; called by muse, mutect2, varscan2
- FRMPD3 | c.1244T>C p.L415P | Missense Mutation (SNP) | VAF 61/121 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99346153; called by muse, mutect2, varscan2
- FSCB | c.989C>A p.P330H | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV100469217, COSV61216583; called by muse, mutect2, varscan2
- FYTTD1 | c.647G>A p.R216K | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV54082822, COSV99611496; called by muse, mutect2, varscan2
- GIMAP8 | c.1846G>A p.A616T | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.071); catalogued as COSV100217494; called by muse, mutect2, varscan2
- GRAMD1C | c.262T>G p.Y88D | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100822876; called by muse, mutect2
- HEPACAM2 | c.235T>C p.Y79H (on ENST00000394468 / NM_001039372.4; = p.Y67H on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV100506509; called by muse, mutect2, varscan2
- HLF | c.25C>A p.P9T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.243); catalogued as COSV99872082; called by mutect2, varscan2
- HS3ST5 | c.470C>A p.P157Q | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100450726; called by muse, mutect2, varscan2
- IGHV3-11 | c.66G>T p.Q22H | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.271); catalogued as rs368419665; called by muse, mutect2, varscan2
- IGKV2D-30 | c.342G>T p.M114I | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs1350918027; called by muse, mutect2, varscan2
- IQSEC3 | c.2611G>T p.V871L (on ENST00000538872 / NM_001170738.2; = p.V568L on NM_015232.1) | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as COSV100407067; called by muse, mutect2, varscan2
- KIF17 | c.1728C>A p.F576L | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV56118987, COSV99928909; called by muse, mutect2, varscan2
- KIT | c.2321A>G p.Y774C | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99853964; called by muse, mutect2, varscan2
- KLF11 | c.1418C>G p.A473G | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV100007737; called by muse, mutect2, varscan2
- KLHL6 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.027); catalogued as COSV100384537; called by muse, mutect2, varscan2
- LAMB4 | c.3301T>C p.C1101R | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99223713; called by muse, mutect2, varscan2
- LDAH | c.899A>G p.H300R | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99425541; called by muse, mutect2
- LDB2 | c.997G>T p.G333C | Missense Mutation (SNP) | VAF 59/210 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100453426; called by muse, mutect2, varscan2
- LIPN | c.1021G>A p.G341S | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101356222; called by muse, mutect2, varscan2
- LMAN2L | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as CM160656, COSV99383293; called by muse, mutect2, varscan2
- LRFN5 | c.1701C>A p.S567R | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.635); catalogued as COSV53251137, COSV99983365; called by muse, varscan2
- LRP3 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV99472191; called by muse, mutect2, varscan2
- LRP5 | c.1450A>G p.I484V | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.823); catalogued as COSV99591833; called by muse, mutect2, varscan2
- MAP3K4 | c.1528G>C p.D510H | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.347); catalogued as COSV100815279; called by muse, mutect2, varscan2
- MLXIPL | c.1916G>A p.R639Q | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.921); catalogued as rs781908299, COSV57668202; called by muse, mutect2, varscan2
- MRPL32 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV99785816; called by muse, mutect2, varscan2
- MYH8 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV101238380, COSV67969950; called by muse, mutect2, varscan2
- NEXMIF | c.3181G>T p.D1061Y | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99280516; called by muse, mutect2, varscan2
- NFKB1 | c.2105G>T p.G702V (on ENST00000394820 / NM_001382627.1; = p.G703V on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99897037; called by muse, mutect2, varscan2
- NOSTRIN | c.1099T>C p.S367P (on ENST00000317647 / NM_001039724.4; = p.S289P on NM_052946.3) | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as COSV100473433; called by muse, mutect2, varscan2
- OR14I1 | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV100700470; called by muse, mutect2, varscan2
- OR1D2 | c.175G>A p.V59M | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768055930, COSV58921888; called by muse, mutect2, varscan2
- OR2C1 | c.461G>C p.G154A | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100514911, COSV59241435; called by muse, mutect2, varscan2
- OR4M1 | c.73C>A p.L25I | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.44); catalogued as COSV100271140; called by muse, mutect2, varscan2
- OR5T2 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.468); catalogued as COSV100506902; called by muse, mutect2, varscan2
- OR5W2 | c.168C>A p.H56Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV100747599; called by muse, mutect2, varscan2
- OR8K1 | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as COSV99687262; called by muse, mutect2, varscan2
- PCDH10 | c.2152C>T p.L718F | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs746365225, COSV99993404; called by muse, mutect2, varscan2
- PCDHA6 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.132); catalogued as COSV65351129; called by mutect2, varscan2
- PCDHGA10 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53939695; called by muse, mutect2, varscan2
- POGLUT2 | c.647C>G p.A216G | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.913); catalogued as COSV101050784, COSV65683037; called by muse, mutect2, varscan2
- PPP1R3A | c.1412A>G p.E471G | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV52895679, COSV99492652; called by muse, mutect2, varscan2
- PTX4 | c.998T>A p.L333Q (on ENST00000447419 / NM_001328608.2; = p.L328Q on NM_001013658.1) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV99560389; called by muse, mutect2, varscan2
- SCN2A | c.2471A>G p.N824S | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99331194; called by muse, mutect2, varscan2
- SCN2A | c.3122C>T p.P1041L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as COSV51840749; called by muse, mutect2, varscan2
- SCN2A | c.5196C>G p.D1732E | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99331199; called by muse, mutect2, varscan2
- SETD1A | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as COSV99352827; called by muse, mutect2, varscan2
- SH3KBP1 | c.1346T>C p.I449T | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs764969436, COSV101115981; called by muse, mutect2, varscan2
- SLFN11 | c.2576G>A p.G859D | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs1328037924, COSV100390550; called by muse, mutect2, varscan2
- SPHKAP | c.3034G>A p.E1012K | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100764060; called by muse, mutect2, varscan2
- SPTB | c.1156G>T p.G386W | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101072075; called by muse, mutect2, varscan2
- STK31 | c.2919G>C p.L973F | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100669308; called by muse, mutect2, varscan2
- SUPT16H | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99359804; called by muse, mutect2, varscan2
- TAF5L | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.185); catalogued as COSV51088565, COSV99273057, COSV99273174; called by muse, mutect2, varscan2
- TG | c.8140G>T p.D2714Y | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55086170, COSV99602216; called by muse, mutect2, varscan2
- TLX3 | c.389G>A p.S130N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV99740581; called by muse, mutect2, varscan2
- TRPC5 | c.1989C>G p.I663M | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.918); catalogued as COSV53297760, COSV99460506; called by muse, mutect2, varscan2
- TTC29 | c.1226T>C p.M409T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as rs1244276955, COSV100283621; called by muse, mutect2, varscan2
- TTN | c.98500A>G p.K32834E (on ENST00000591111; = p.K25410E on NM_003319.4) | Missense Mutation (SNP) | VAF 15/106 reads (14%) | PolyPhen benign (0.009); catalogued as COSV100607469; called by muse, mutect2, varscan2
- TTN | c.14696T>C p.M4899T (on ENST00000591111; = p.M3972T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/170 reads (12%) | PolyPhen benign (0); catalogued as COSV100607480; called by muse, mutect2, varscan2
- TUBGCP6 | c.3707G>A p.R1236Q | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.99); catalogued as rs763977994, COSV99955395, COSV99956446; called by muse, mutect2
- UGT2B17 | c.413T>A p.M138K | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100497207; called by muse, mutect2, varscan2
- UMOD | c.1487T>G p.L496R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.568); catalogued as COSV100208234; called by muse, mutect2, varscan2
- VPS9D1 | c.446T>C p.L149P | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV101231989; called by muse, mutect2, varscan2
- WNT2 | c.152A>T p.Q51L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99626008; called by muse, mutect2, varscan2
- ZFC3H1 | c.3199G>T p.E1067* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as COSV101110484; called by muse, mutect2, varscan2
- ZNF107 | c.365A>G p.H122R | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV100788341; called by muse, mutect2
- ZNF419 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99692077; called by muse, mutect2, varscan2
- ZNF585B | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV100459406; called by muse, mutect2, varscan2
- ZRANB3 | c.981G>C p.K327N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs762530793, COSV51507525, COSV99923364; called by muse, mutect2, varscan2
- DNAJC2 | c.1853_1863del p.R618Mfs*11 | Frame Shift Del (DEL) | VAF 9/72 reads (13%) | called by mutect2, pindel, varscan2
- IGKV1D-43 | c.12G>T p.R4S | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- LRRC31 | c.138del p.S47Afs*45 | Frame Shift Del (DEL) | VAF 35/136 reads (26%) | called by mutect2, pindel, varscan2
- SART3 | c.2368G>A p.G790R (on ENST00000228284; = p.G772R on NM_014706.4) | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TRMU | c.1173_1183del p.Y391* | Frame Shift Del (DEL) | VAF 99/163 reads (61%) | called by mutect2, pindel, varscan2
- ZNF492 | c.1370del p.A457Vfs*13 | Frame Shift Del (DEL) | VAF 17/88 reads (19%) | called by mutect2, pindel, varscan2
- ADGRA3 | c.318C>A p.L106= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV100529838; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3996A>T p.A1332= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV99782941; called by muse, mutect2, varscan2
- ARHGAP12 | c.84G>A p.K28= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV100260534; called by muse, mutect2, varscan2
- COL14A1 | c.1353G>C p.L451= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV99918876; called by muse, mutect2, varscan2
- COX7B2 | c.111A>G p.K37= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV100260489; called by muse, mutect2, varscan2
- FAM135B | c.492C>A p.I164= | Silent (SNP) | VAF 35/146 reads (24%) | catalogued as COSV99356914; called by muse, mutect2, varscan2
- FBXL2 | c.559C>T p.L187= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV99371845; called by muse, mutect2, varscan2
- HENMT1 | c.1116G>C p.L372= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV100898651; called by muse, mutect2
- HIPK2 | c.3144C>T p.T1048= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV101301625; called by muse, mutect2, varscan2
- IQSEC3 | c.2610G>T p.L870= (on ENST00000538872 / NM_001170738.2; = p.L567= on NM_015232.1) | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV100407066; called by muse, mutect2, varscan2
- ITM2A | c.468G>A p.L156= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV100964444; called by muse, mutect2, varscan2
- LAMA2 | c.5937C>T p.N1979= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs747714599, COSV70345709; called by muse, mutect2, varscan2
- LMO7 | c.3258A>G p.S1086= (on ENST00000357063; = p.S767= on NM_005358.5) | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as rs1428510610, COSV58531783; called by muse, mutect2, varscan2
- LSAMP | c.207C>A p.G69= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as COSV100370109; called by muse, mutect2
- LSM11 | c.546C>A p.V182= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as COSV99643928; called by muse, mutect2, varscan2
- NLRX1 | c.306A>T p.P102= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV99424119; called by muse, mutect2, varscan2
- NOS1AP | c.609T>A p.T203= | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as COSV100723115; called by muse, mutect2, varscan2
- OR10G7 | c.246C>A p.T82= | Silent (SNP) | VAF 25/164 reads (15%) | catalogued as COSV100389886, COSV57868999; called by muse, mutect2, varscan2
- OR10G9 | c.246C>A p.T82= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV100901579; called by muse, mutect2, varscan2
- OR10H1 | c.237G>A p.P79= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs1318938738, COSV58472317, COSV58472669; called by muse, mutect2, varscan2
- PCDHGA10 | c.456G>T p.A152= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99536278; called by muse, mutect2, varscan2
- POGLUT2 | c.648C>T p.A216= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV101050783; called by muse, mutect2, varscan2
- PRAMEF18 | c.792C>G p.L264= | Silent (SNP) | VAF 20/285 reads (7%) | called by muse, mutect2
- RAB11FIP3 | c.1320G>C p.G440= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV99240170; called by muse, mutect2, varscan2
- SLC24A4 | c.645C>A p.I215= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV100104916, COSV54106906; called by muse, mutect2, varscan2
- TMCO3 | c.1950G>A p.T650= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs775210162, COSV100952251; called by muse, mutect2, varscan2
- TMEM69 | c.114C>G p.L38= | Silent (SNP) | VAF 95/307 reads (31%) | catalogued as COSV100739501; called by muse, mutect2, varscan2
- TTN | c.60T>A p.G20= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV100607486; called by muse, mutect2
- TUBGCP5 | c.768G>A p.L256= | Silent (SNP) | VAF 20/61 reads (33%) | called by muse, varscan2
- ZNF423 | c.3213C>G p.L1071= (on ENST00000563137 / NM_001379286.1; = p.L1063= on NM_015069.4) | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV99281162; called by muse, mutect2
- ZNF835 | c.174C>T p.S58= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV101606321; called by muse, mutect2, varscan2
- BIRC8 | n.1596C>A | RNA (SNP) | VAF 17/69 reads (25%) | catalogued as COSV100136387; called by muse, mutect2, varscan2
- CR1 | c.487+12187C>T | Intron (SNP) | VAF 31/193 reads (16%) | catalogued as rs1469085098, COSV100887542; called by muse, mutect2, varscan2
- Y_RNA | chr14:50091593 G>C | 3'Flank (SNP) | VAF 22/75 reads (29%) | called by muse, mutect2, varscan2
